Somatic mutation profile of tumor specimen TCGA-EY-A1GT-01A (aliquot TCGA-EY-A1GT-01A-11D-A13L-09) from TCGA case TCGA-EY-A1GT, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G1; Age at diagnosis: 68.9 years (25,151 days).
Specimen TCGA-EY-A1GT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60314316-0a3c-4fc5-b071-dd24f717c586.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EY-A1GT-10A (Blood Derived Normal), aliquot TCGA-EY-A1GT-10A-01D-A13O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e7ec5b0-4a7f-4f12-ba74-194de142e347

The open-access MAF lists 83 somatic variants for this specimen: 65 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 17, Frame Shift Del 5, Nonsense Mutation 4, Frame Shift Ins 2, Intron 1, Splice Region 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1511G>A p.G504E (on ENST00000288602 / NM_001374244.1; = p.G464E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121913348, CM086781, COSV56066746, COSV56075378; ClinVar: pathogenic / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 19/47 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 32/112 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- PTEN | c.445C>T p.Q149* | Nonsense Mutation (SNP) | VAF 82/131 reads (63%) | catalogued as rs1060500122, CM110149, COSV64288740, COSV64297241; ClinVar: pathogenic; called by muse, varscan2
- ACTN1 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV99518378; called by muse, mutect2, varscan2
- AL031777.2 | c.203G>C p.G68A | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100587256; called by muse, mutect2, varscan2
- ARHGDIA | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.014); catalogued as rs754320727, COSV99482624; called by muse, mutect2, varscan2
- ARID1A | c.2032C>T p.Q678* | Nonsense Mutation (SNP) | VAF 19/57 reads (33%) | catalogued as COSV61379976; called by muse, mutect2, varscan2
- ARMC12 | c.185G>A p.R62Q (on ENST00000373866 / NM_001286574.2; = p.R89Q on NM_145028.5) | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0.223); catalogued as rs138730820, COSV99849568; called by muse, mutect2, varscan2
- ATG2B | c.2281C>G p.L761V | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100738181; called by muse, mutect2, varscan2
- ATN1 | c.1696C>T p.P566S | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.015); catalogued as rs138403084; called by muse, mutect2, varscan2
- BSN | c.8671C>T p.R2891C | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56514027; called by muse, mutect2, varscan2
- CCDC115 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as COSV99383830; called by muse, mutect2, varscan2
- CD1E | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.409); catalogued as rs1469396381, COSV63771045; called by muse, mutect2, varscan2
- CDK9 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1340146157, COSV100953572; called by muse, mutect2, varscan2
- CHM | c.1451C>T p.T484I | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.222); catalogued as COSV100753579; called by muse, mutect2, varscan2
- DENND4B | c.2128C>T p.R710W | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as rs1372689101, COSV63407274; called by muse, mutect2, varscan2
- DGKH | c.2560G>T p.A854S | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.944); catalogued as COSV54943354; called by muse, mutect2
- DHPS | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV99269741; called by muse, mutect2, varscan2
- DIAPH2 | c.1459A>C p.K487Q | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0.043); catalogued as COSV100234620; called by muse, mutect2, varscan2
- DNAH7 | c.8751C>A p.Y2917* | Nonsense Mutation (SNP) | VAF 20/52 reads (38%) | catalogued as COSV100416968; called by muse, mutect2, varscan2
- DPP7 | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as rs756165436, COSV65371443; called by muse, mutect2
- EFEMP2 | c.964G>A p.V322I | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.989); catalogued as rs759573856, COSV100337368; called by muse, mutect2, varscan2
- EPG5 | c.461G>T p.S154I | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.225); catalogued as COSV99957904; called by muse, mutect2, varscan2
- FAM71A | c.1748C>T p.P583L | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs201631987, COSV99674860; called by muse, mutect2, varscan2
- FAT2 | c.6350G>A p.R2117Q | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.933); catalogued as rs763727182, COSV55825497; called by muse, mutect2, varscan2
- GDI1 | c.834G>T p.K278N | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV99341172; called by muse, mutect2, varscan2
- GUCY2C | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.957); catalogued as rs150442498; called by muse, mutect2, varscan2
- HCFC1 | c.1511G>A p.R504Q | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs782663829, COSV100129726; called by muse, mutect2, varscan2
- HSPA4 | c.2040T>C p.N680= | Splice Region (SNP) | VAF 17/52 reads (33%) | catalogued as COSV100507819; called by muse, mutect2, varscan2
- IGHG3 | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.364); catalogued as rs769456444; called by muse, mutect2, varscan2
- KCNJ3 | c.1146A>T p.R382S | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.089); catalogued as COSV99716338; called by muse, mutect2, varscan2
- KIF13A | c.1943G>A p.R648H | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs932259103, COSV52448594; called by muse, mutect2, varscan2
- KIF19 | c.2089G>A p.A697T | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768247734, COSV63429262; called by muse, mutect2, varscan2
- KIF1A | c.3527G>A p.R1176Q | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99064854; called by muse, mutect2, varscan2
- MAGEA3 | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as COSV100938988, COSV64755810; called by muse, mutect2, varscan2
- MAP1S | c.2929G>A p.V977I | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.106); catalogued as rs554296571, COSV100141181; called by muse, mutect2, varscan2
- MTCL1 | c.2414T>C p.L805P (on ENST00000306329 / NM_001378206.1; = p.L445P on NM_015210.4) | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV100095385; called by muse, mutect2, varscan2
- MUC5B | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as rs748172935, COSV71595473; called by muse, mutect2, varscan2
- MYO5B | c.1077C>G p.S359R | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV99546065; called by muse, mutect2, varscan2
- NCAM2 | c.1364G>A p.G455E | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.152); catalogued as rs1388555903, COSV53100552; called by muse, mutect2, varscan2
- OCRL | c.2582-2A>G p.X861_splice | Splice Site (SNP) | VAF 28/88 reads (32%) | catalogued as CS113491, COSV100843535; called by muse, mutect2, varscan2
- OR2M4 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 83/119 reads (70%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as rs200070415, COSV100141171; called by muse, mutect2, varscan2
- OR4F6 | c.430T>G p.F144V | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.236); catalogued as COSV100186973; called by muse, mutect2, varscan2
- PCDH18 | c.3308A>G p.N1103S | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100787469; called by muse, mutect2, varscan2
- PCDHAC2 | c.610A>G p.S204G | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.05); catalogued as COSV99155044; called by muse, mutect2, varscan2
- PCLO | c.3499G>A p.E1167K | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.311); catalogued as COSV100436550; called by muse, mutect2, varscan2
- PRSS35 | c.757C>T p.R253W | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1263494157, COSV63800270; called by muse, mutect2, varscan2
- RIMS1 | c.1577G>A p.R526Q | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as rs1201225464, COSV53489894; called by muse, mutect2, varscan2
- RPH3A | c.1444G>A p.V482I (on ENST00000389385 / NM_001143854.2; = p.V478I on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs780022678, COSV101231881; called by muse, mutect2, varscan2
- SCRIB | c.3707del p.P1236Qfs*29 | Frame Shift Del (DEL) | VAF 32/89 reads (36%) | catalogued as COSV100254263; called by mutect2, pindel, varscan2
- TAF1L | c.166G>A p.V56I | Missense Mutation (SNP) | VAF 52/129 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs1192501986, COSV54262894; called by muse, mutect2, varscan2
- TCERG1 | c.1872A>T p.K624N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.445); catalogued as COSV99695177; called by mutect2, varscan2
- TFEC | c.208G>A p.G70S | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs759434961, COSV99625071; called by muse, mutect2, varscan2
- TMEM209 | c.673G>A p.V225I | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs756606396, COSV100390567; called by muse, mutect2, varscan2
- U2SURP | c.1118C>T p.T373M | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as COSV101204553; called by muse, mutect2, varscan2
- ZFHX3 | c.3628C>T p.R1210* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as COSV51709176; called by muse, mutect2, varscan2
- ZMYM2 | c.2068_2069del p.L690Sfs*2 | Frame Shift Del (DEL) | VAF 14/48 reads (29%) | catalogued as rs1474114489; called by pindel, varscan2
- ZNF536 | c.3136C>T p.R1046W | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs144763919; called by muse, mutect2, varscan2
- ARID1A | c.2665_2666dup p.M890Afs*2 | Frame Shift Ins (INS) | VAF 11/35 reads (31%) | called by mutect2, pindel, varscan2
- COL19A1 | c.2603_2605del p.E868del | In Frame Del (DEL) | VAF 29/68 reads (43%) | called by mutect2, pindel, varscan2
- SOX17 | c.403dup p.Y135Lfs*27 | Frame Shift Ins (INS) | VAF 17/45 reads (38%) | called by mutect2, pindel, varscan2
- SYCP2 | c.946_947del p.S316Ifs*7 | Frame Shift Del (DEL) | VAF 17/52 reads (33%) | called by pindel, varscan2
- TLE1 | c.1945del p.R649Gfs*38 | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | called by mutect2, pindel, varscan2
- ZMYM2 | c.2610del p.K870Nfs*68 | Frame Shift Del (DEL) | VAF 21/69 reads (30%) | called by mutect2, pindel, varscan2
- C1orf127 | c.798G>A p.S266= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs747608939, COSV65438291; called by muse, mutect2, varscan2
- CAPRIN1 | c.417A>G p.E139= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV100404168; called by muse, mutect2, varscan2
- CIC | c.696G>A p.K232= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs1285460447, COSV50624908; called by muse, mutect2, varscan2
- DDX4 | c.813C>T p.Y271= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs146554855, COSV61756464; called by muse, mutect2, varscan2
- DOK7 | c.480C>T p.Y160= | Silent (SNP) | VAF 49/109 reads (45%) | catalogued as rs550024569, CM077180, COSV60773983; called by muse, mutect2, varscan2
- FKBP5 | c.316C>T p.L106= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as COSV100616379; called by muse, mutect2, varscan2
- FOXL2NB | c.345G>A p.S115= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as rs769531270, COSV100374768; called by muse, mutect2, varscan2
- IGLV3-25 | c.108G>A p.T36= | Silent (SNP) | VAF 35/104 reads (34%) | catalogued as rs750022961; called by muse, mutect2, varscan2
- IRX6 | c.198C>T p.A66= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as rs201160693, COSV99306731; called by muse, mutect2, varscan2
- LLGL1 | c.1389G>A p.S463= | Silent (SNP) | VAF 32/55 reads (58%) | catalogued as rs759834279, COSV100375028; called by muse, mutect2, varscan2
- MEFV | c.684C>T p.P228= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as COSV54818221; called by muse, mutect2, varscan2
- MMEL1 | c.663G>A p.A221= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs369377247; called by muse, mutect2, varscan2
- MRPS2 | c.489C>T p.G163= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs200121042, COSV54092883; called by muse, mutect2, varscan2
- PIK3C2B | c.621C>T p.I207= | Silent (SNP) | VAF 38/62 reads (61%) | catalogued as COSV100915078; called by muse, mutect2
- SDR39U1 | c.408A>C p.V136= | Silent (SNP) | VAF 28/63 reads (44%) | catalogued as COSV99250040; called by muse, mutect2, varscan2
- SMG1 | c.1086T>A p.G362= | Silent (SNP) | VAF 75/183 reads (41%) | catalogued as COSV101246695; called by muse, mutect2, varscan2
- VWA7 | c.630C>T p.S210= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs775453388, COSV100791848; called by muse, mutect2, varscan2
- HTR3D | c.511+25C>T | Intron (SNP) | VAF 17/57 reads (30%) | catalogued as COSV100488276; called by muse, mutect2, varscan2
